MMRF case MMRF_1915 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/12ade16c-661c-48cd-b959-30890afb1040

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.4 years (22,051 days); ISS stage: I; Days to last known disease status: 983 days (2.7 years); Days to last follow up: 983 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 25 days; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 53 days; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 358 days; Days to treatment end: 365 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 395 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.5 mg/dL; Immunoglobulin G 2.66 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.3 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL.
- Day 82 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.32 mg/dL; Immunoglobulin G 2.72 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 9.52 mmol/L.
- Day 173 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.225 mg/dL; Immunoglobulin G 3.7 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.53 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.67 mmol/L.
- Day 269 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.285 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.672 mg/dL; Immunoglobulin G 4.78 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.53 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 353 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.285 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.478 mg/dL; Immunoglobulin G 4.52 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.
- Day 445 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.895 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 5.33 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6.66 mmol/L.
- Day 551 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 5.97 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.23 mmol/L.
- Day 675 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 4.86 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 766 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Hemoglobin 5.89 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 850 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.808 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.921 mg/dL; Immunoglobulin G 4.81 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 915 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.827 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.686 mg/dL; Immunoglobulin G 4.76 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.12 mmol/L.
- Day 983 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.455 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.686 mg/dL; Immunoglobulin G 5.56 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 6.71 mmol/L.

Other clinical attributes
- Day 1: Weight: 73 kg; Height: 169 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1915_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1915_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
